Gene-level copy-number profile of tumor specimen ALCH-B1PZ-TTP1-A from ALCHEMIST case ALCH-B1PZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,087 days).
Specimen ALCH-B1PZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df4ff797-e76d-4d7a-a8a6-3f48462f23cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1PZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/ace4c7bc-09f1-4f62-9b00-ce0706f805a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,655; copy number 2: 55,905; copy number 3: 136; copy number 4: 10; copy number 7: 99; copy number 12: 28; copy number 13: 78.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 205 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,747,727–57,756,013, 1 gene, copy number 7 (within-gene range 2–7): CDK4.
- chr12:57,755,103–57,959,148, 17 genes, copy number 7: MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr12:65,645,992–73,208,317, 137 genes, copy number 7–13 (broad region; genes not listed).
- chr16:46,469,341–46,831,180, 15 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87.
- chr16:47,077,703–48,620,148, 35 genes, copy number 7 (within-gene range 2–7): NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44.

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
